Somatic mutation profile of tumor specimen TCGA-EJ-A8FS-01A (aliquot TCGA-EJ-A8FS-01A-11D-A34U-08) from TCGA case TCGA-EJ-A8FS, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.7 years (24,380 days).
Specimen TCGA-EJ-A8FS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e890f590-3108-4073-b48d-6fd9a9d0951b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-A8FS-10A (Blood Derived Normal), aliquot TCGA-EJ-A8FS-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1302046-cbc8-4a01-ba09-83adcab4f3f0

The open-access MAF lists 34 somatic variants for this specimen: 26 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 19, Silent 8, Nonsense Mutation 4, Frame Shift Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.305T>C p.F102S | Missense Mutation (SNP) | VAF 58/137 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61652830, COSV61654088, COSV61654168; called by muse, mutect2, varscan2
- ALPK2 | c.1557A>T p.R519S | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV100864204; called by muse, mutect2, varscan2
- APC | c.3367C>T p.Q1123* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as CM011276, COSV57331639; called by muse, mutect2, varscan2
- ASH1L | c.5081C>G p.S1694* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100853230, COSV64214692; called by muse, mutect2, varscan2
- CHRNA9 | c.820A>G p.T274A | Missense Mutation (SNP) | VAF 84/239 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100038869; called by muse, mutect2, varscan2
- CYP2A13 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100386687; called by muse, mutect2
- DENND11 | c.505C>G p.H169D | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as COSV101530700; called by muse, mutect2, varscan2
- DNASE2 | c.980G>T p.C327F | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99262563; called by muse, mutect2, varscan2
- EGR1 | c.499C>G p.P167A | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99525362; called by muse, mutect2, varscan2
- EPB41L3 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 56/167 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV59454602; called by muse, mutect2, varscan2
- ITIH2 | c.36T>A p.F12L | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV100623224; called by muse, mutect2, varscan2
- KCNB2 | c.1997C>T p.T666M | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.306); catalogued as rs758297898, COSV73050312; called by muse, mutect2, varscan2
- MARCO | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.952); catalogued as rs377491060; called by muse, mutect2, varscan2
- MLPH | c.74A>T p.D25V | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99221987; called by muse, mutect2, varscan2
- MYH11 | c.5662G>A p.E1888K | Missense Mutation (SNP) | VAF 68/268 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100258120; called by muse, mutect2, varscan2
- N4BP2 | c.3308C>A p.S1103* | Nonsense Mutation (SNP) | VAF 20/59 reads (34%) | catalogued as COSV99788350; called by muse, mutect2, varscan2
- NUP133 | c.3274C>T p.P1092S | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54574520, COSV99772730; called by muse, mutect2, varscan2
- PDE9A | c.1633G>T p.E545* | Nonsense Mutation (SNP) | VAF 22/29 reads (76%) | catalogued as COSV99371220; called by muse, mutect2, varscan2
- SLF2 | c.1256C>G p.S419C | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.639); catalogued as COSV53272641; called by muse, mutect2, varscan2
- SMC2 | c.1556G>C p.R519T | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.392); catalogued as COSV99658185; called by muse, varscan2
- TIAM2 | c.3390G>C p.Q1130H | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99265208; called by muse, mutect2, varscan2
- TRAP1 | c.1636A>C p.K546Q | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.023); catalogued as rs143144399; called by muse, mutect2, varscan2
- FAM217B | c.627del p.T210Lfs*9 | Frame Shift Del (DEL) | VAF 22/57 reads (39%) | called by mutect2, pindel, varscan2
- RFPL4B | c.663dup p.D222* | Frame Shift Ins (INS) | VAF 16/41 reads (39%) | called by mutect2, pindel, varscan2
- RNF20 | c.872_873del p.H291Lfs*14 | Frame Shift Del (DEL) | VAF 24/62 reads (39%) | called by pindel, varscan2
- TRDC | c.401G>C p.R134P | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ARHGAP33 | c.3024C>T p.Y1008= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as rs765929698, COSV50122033; called by muse, mutect2, varscan2
- FAT1 | c.7149C>T p.L2383= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV101499165, COSV71674269; called by muse, mutect2, varscan2
- FZD10 | c.501G>A p.P167= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs772214243, COSV99969314; called by mutect2, varscan2
- OTX1 | c.567G>A p.A189= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV56996079; called by muse, mutect2, varscan2
- PCDHA7 | c.1536G>T p.A512= | Silent (SNP) | VAF 67/176 reads (38%) | catalogued as rs782150478, COSV100971320, COSV100971859; called by muse, mutect2, varscan2
- PDZD2 | c.5478T>C p.P1826= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as COSV99224290; called by muse, mutect2, varscan2
- PPP1R13B | c.1146A>G p.K382= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV99157994; called by muse, mutect2, varscan2
- SLC38A3 | c.765C>T p.H255= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs766695205, COSV101309888; called by muse, mutect2, varscan2
